Somatic mutation profile of tumor specimen 0DT9NP from CCDI case PBCJIX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,173 days).
Specimen 0DT9NP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58ac2949-caa5-4d08-bf1a-36380c527518.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9NC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2df383e-9448-4c4d-931c-3b433bc30cdf

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAF1 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 175/658 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52582783; called by muse, mutect2, varscan2
- SPPL2B | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761928273; called by muse, mutect2, varscan2
- ARHGEF35 | c.58T>A p.F20I | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- AARD | c.21C>T p.R7= | Silent (SNP) | VAF 54/480 reads (11%) | called by muse, mutect2, varscan2
- MID1IP1 | c.-65C>T | 5'UTR (SNP) | VAF 94/128 reads (73%) | called by muse, mutect2, varscan2
